Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7423, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7423-01A (Primary Tumor).

DIAGNOSIS

- (A) RIGHT PARTIAL GLOSSECTOMY:
INVASIVE WELL DIFFERENTIATED SQUAMOUS CELL CARCINOMA.
(SEE COMMENT)
Peripheral and deep margins of resection, free of tumor.
- (B) TEETH:
Two teeth (gross only).

COMMENT

The tumor has a maximum depth of invasion of 0.8 cm in an area where the specimen thickness is 1.4 cm. No unequivocal vascular/lymphatic or perineural invasion is identified.

SPECIMEN

- (A) RIGHT PARTIAL GLOSSECTOMY:
(B) TEETH:

SNOMED CODES

T-53000, M-80703

Source: NCI Genomic Data Commons file 10261555-9fa8-4bd5-8aff-c791547bc4f9 (TCGA-CV-7423.9D42D07F-0960-47D1-942D-4F26C9C01ADC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).